Somatic mutation profile of tumor specimen TCGA-13-0805-01A (aliquot TCGA-13-0805-01A-01W-0371-08) from TCGA case TCGA-13-0805, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 57.5 years (21,014 days).
Specimen TCGA-13-0805-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c177e1d0-d0fb-4c4e-8692-fd87e451095c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0805-10A (Blood Derived Normal), aliquot TCGA-13-0805-10A-01W-0371-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/365e4b47-67d3-40a9-8f31-a6d302555400

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 6, Nonsense Mutation 1, Intron 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 215/299 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CDC42BPB | c.3673G>T p.V1225F | Missense Mutation (SNP) | VAF 33/39 reads (85%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV100775720; called by muse, mutect2, varscan2
- CERKL | c.1142C>G p.A381G (on ENST00000339098 / NM_001030311.2; = p.A355G on NM_201548.5) | Missense Mutation (SNP) | VAF 351/849 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.627); catalogued as COSV100184289; called by muse, mutect2, varscan2
- CHD7 | c.4272G>A p.M1424I | Missense Mutation (SNP) | VAF 160/438 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV101418590; called by muse, mutect2, varscan2
- DPP6 | c.2114G>A p.R705H (on ENST00000377770 / NM_001364500.2; = p.R643H on NM_001936.5) | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs550563959, COSV59595739; called by muse, mutect2, varscan2
- IL12RB2 | c.1303G>C p.D435H | Missense Mutation (SNP) | VAF 140/375 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52026678; called by muse, mutect2, varscan2
- LRP1 | c.7370G>A p.R2457H | Missense Mutation (SNP) | VAF 56/167 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1203320154, COSV99677287; called by muse, mutect2, varscan2
- MYH1 | c.2417A>G p.Q806R | Missense Mutation (SNP) | VAF 70/112 reads (63%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99875122, COSV99877205; called by muse, mutect2, varscan2
- NEU1 | c.689G>A p.C230Y | Missense Mutation (SNP) | VAF 83/162 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV99999378; called by muse, mutect2, varscan2
- PLOD1 | c.1825G>T p.E609* | Nonsense Mutation (SNP) | VAF 17/27 reads (63%) | catalogued as rs1464654878, COSV52142657, COSV99539276; called by muse, mutect2, varscan2
- PSG5 | c.830G>T p.G277V | Missense Mutation (SNP) | VAF 265/414 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV100743267, COSV61654904; called by muse, mutect2, varscan2
- SGK2 | c.970C>G p.L324V | Missense Mutation (SNP) | VAF 103/245 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV100414890; called by muse, mutect2, varscan2
- ZNF133 | c.1853A>C p.K618T (on ENST00000316358 / NM_001352454.2; = p.K617T on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 97/293 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV100315702; called by muse, mutect2, varscan2
- ZNF470 | c.991C>G p.Q331E | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100401443; called by muse, mutect2, varscan2
- NFKBIA | c.847_848del p.S283* | Frame Shift Del (DEL) | VAF 45/142 reads (32%) | called by pindel, varscan2
- TOP2A | c.578_580del p.T193_W194delinsR | In Frame Del (DEL) | VAF 685/1598 reads (43%) | called by pindel, varscan2
- ANK1 | c.885G>T p.G295= | Silent (SNP) | VAF 77/226 reads (34%) | catalogued as COSV99227291; called by muse, mutect2, varscan2
- CBLB | c.1551C>A p.G517= | Silent (SNP) | VAF 235/587 reads (40%) | catalogued as COSV99914648; called by muse, mutect2, varscan2
- MBD6 | c.2838C>T p.V946= | Silent (SNP) | VAF 44/144 reads (31%) | catalogued as rs1555172195, COSV100851868; called by muse, mutect2, varscan2
- MIPEP | c.1128A>G p.L376= | Silent (SNP) | VAF 12/161 reads (7%) | catalogued as rs1048616079, COSV101193291; called by muse, mutect2
- PCSK2 | c.1194G>T p.L398= | Silent (SNP) | VAF 46/116 reads (40%) | called by muse, mutect2
- TCERG1L | c.1209C>A p.S403= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV100894692; called by muse, mutect2, varscan2
- GRM5 | c.661+62501G>T | Intron (SNP) | VAF 52/144 reads (36%) | catalogued as COSV100555025; called by mutect2, varscan2
